Surgical pathology report (de-identified scan), TCGA case TCGA-DH-5142, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-5142-01A (Primary Tumor).

[page 1 of 2]
TCGA - DH - 5142

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

CLINICAL HISTORY: [REDACTED] male, here for left side craniotomy for tumor.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and [REDACTED]

A. Brain tumor

B. Brain tumor

A. The specimen is received fresh and consists of a dome-shaped portion of edematous beige to gray-tan homogenous tissue that is 3.2 x 2.5 x 2.0cm. A representative portion is submitted for frozen section. Frozen section diagnosis is "Infiltrating glioma, most likely astrocytic, with features suspicious for anaplasia," by Dr. [REDACTED]. The frozen tissue is submitted in cassette FSA1, and representative tissue is submitted in cassettes A2-A4. A representative portion is submitted for the [REDACTED]

B. The specimen is received fresh and consists of a 3.6 x 3.3 x 0.9 cm portion of homogenous beige to gray-tan soft tissue with focal areas of yellow to white softening. A representative portion is submitted in cassettes B1-B4, and a portion is submitted to [REDACTED]

DIAGNOSIS:

A. "Brain tumor":

Anaplastic astrocytoma (WHO Grade III) (see comment)

B. "Brain tumor":

Anaplastic astrocytoma (WHO Grade III)

COMMENT: This highly infiltrative astrocytoma shows evidence of anaplastic transformation as well as areas of diffuse low grade histology. Areas of increased cellularity and pleomorphism are especially striking in slides A3 and A4. A conspicuous gemistocytic appearance of the tumor cells is apparent throughout (GFAP-immunoreactive). Although only a few mitotic figures are apparent in this well sampled glioma, the Ki-67 labeling index is around 9 % (range: 6-13%) in highly cellular areas. These results support the diagnosis. "I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]

[REDACTED]. Some tests have not been cleared or approved by the U.S. Food and Drug

[page 2 of 2]
Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] a qualified to perform high complexity clinical laboratory testing.

[REDACTED]
Pathologist

Source: NCI Genomic Data Commons file 449f222c-9fb7-4554-b6b6-127a9f370715 (TCGA-DH-5142.D6BAD55B-31F4-416A-8775-E3439C0F6918.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).